Somatic mutation profile of tumor specimen TCGA-32-2495-01A (aliquot TCGA-32-2495-01A-01D-1353-08) from TCGA case TCGA-32-2495, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.8 years (21,860 days).
Specimen TCGA-32-2495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f07cbd4-e922-4868-924f-9d7a90e25a14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2495-10B (Blood Derived Normal), aliquot TCGA-32-2495-10B-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca831040-5eef-4f3b-aef4-5f84f247cd6a

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Nonsense Mutation 4, Splice Site 1, RNA 1, Splice Region 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3149G>A p.G1050D | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs61750062, CM012879, COSV64674576; ClinVar: not provided; called by muse, mutect2, varscan2
- ACSL6 | c.1837C>T p.Q613* (on ENST00000379240; = p.Q638* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/147 reads (64%) | catalogued as COSV57300384; called by muse, mutect2, varscan2
- ADAMTS12 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 163/314 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs374678857, COSV100711433, COSV61260149, COSV61262502; called by muse, mutect2, varscan2
- C1S | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1555162972, COSV61071263; called by muse, varscan2
- CAPN6 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV60695402; called by muse, mutect2, varscan2
- CCDC150 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 45/144 reads (31%) | catalogued as rs200403800; called by muse, mutect2, varscan2
- CFAP47 | c.4691G>T p.R1564M | Missense Mutation (SNP) | VAF 117/235 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100545075, COSV57974668; called by muse, mutect2, varscan2
- CFAP54 | c.6271C>T p.P2091S | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61571601; called by muse, mutect2, varscan2
- COBLL1 | c.2931T>A p.N977K (on ENST00000392717; = p.N939K on NM_014900.5) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1273131814, COSV52070124; called by muse, mutect2
- CRISP3 | c.614+1G>A p.X205_splice (on ENST00000371159 / NM_001368123.1; = p.X187_splice on NM_006061.4) | Splice Site (SNP) | VAF 103/137 reads (75%) | catalogued as rs762333204, COSV53819771, COSV53821819; called by muse, mutect2, varscan2
- DRD5 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs867973828, COSV58577896; called by muse, mutect2, varscan2
- ELP2 | c.1751C>G p.S584* | Nonsense Mutation (SNP) | VAF 59/202 reads (29%) | catalogued as COSV60851876; called by muse, mutect2, varscan2
- EP400 | c.6221T>A p.I2074N | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57776184; called by muse, mutect2
- FBN3 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54464173; called by muse, mutect2, varscan2
- FRMPD4 | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 247/523 reads (47%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs771597592, COSV66215660, COSV66217173; called by muse, varscan2
- GLI3 | c.3590T>C p.M1197T | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV67890190; called by muse, mutect2
- GRIA3 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 268/488 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1246651385, COSV52053773; called by muse, mutect2, varscan2
- KRT37 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV56658554, COSV99845625; called by muse, mutect2, varscan2
- LCT | c.250A>T p.I84F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV51467235; called by muse, mutect2, varscan2
- MAP3K5 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62889959; called by muse, mutect2
- MARK3 | c.1057A>C p.K353Q | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53511817, COSV99357902; called by muse, mutect2, varscan2
- MET | c.1036T>C p.F346L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59263122; called by muse, mutect2, varscan2
- MET | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.753); catalogued as rs749738523, COSV59263129; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MYH11 | c.5352G>C p.E1784D | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as COSV55557684; called by muse, mutect2, varscan2
- NEK10 | c.2417A>C p.E806A | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV55360510; called by muse, mutect2, varscan2
- NRXN1 | c.3955A>C p.T1319P | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV60505200; called by muse, mutect2, varscan2
- OPHN1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 116/219 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100830173, COSV62783351; called by muse, mutect2, varscan2
- OR14I1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772524548, COSV61200100; called by muse, mutect2, varscan2
- OR4Q3 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59179103; called by muse, mutect2, varscan2
- OTOA | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs148114778; called by muse, mutect2, varscan2
- PDCD4 | c.1212T>C p.G404= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as COSV54523593, COSV99701097; called by muse, mutect2, varscan2
- PTAFR | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as rs184182216, COSV59536809; called by muse, mutect2, varscan2
- PTEN | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 91/130 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.129); catalogued as COSV64291698, COSV99058026; called by muse, mutect2, varscan2
- RDH8 | c.653C>T p.A218V (on ENST00000651512; = p.A198V on NM_015725.4) | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.355); catalogued as rs754093769, COSV50675550; called by muse, mutect2, varscan2
- REN | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1280455872, COSV65817433; called by muse, mutect2, varscan2
- RIPPLY3 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769092772, COSV61566792; called by muse, mutect2, varscan2
- RNF112 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs377199559; called by muse, mutect2, varscan2
- SELPLG | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV57313304; called by muse, varscan2
- SLC15A1 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141206459; called by muse, mutect2, varscan2
- SLC44A5 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs148670291; called by muse, mutect2, varscan2
- SLC49A3 | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as COSV59140804; called by muse, mutect2, varscan2
- SLC49A4 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs760738852, COSV53747649; called by muse, mutect2, varscan2
- TRIM10 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 463/584 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs769895582, COSV64993617; called by muse, mutect2, varscan2
- TRIM65 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs748483118, COSV53932501; called by muse, mutect2, varscan2
- TSHZ3 | c.2923G>A p.V975I | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); catalogued as rs754020316, COSV53665907, COSV53685439; called by muse, mutect2, varscan2
- UBR5 | c.5302G>C p.A1768P | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); catalogued as COSV55290988; called by muse, mutect2, varscan2
- UGT2A1 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs927661180, COSV54142992; called by muse, mutect2, varscan2
- USP47 | c.3202C>T p.H1068Y (on ENST00000399455 / NM_001372095.1; = p.H980Y on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV59694265; called by muse, mutect2, varscan2
- ZC3H15 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 143/332 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61922706; called by muse, mutect2, varscan2
- ZNF274 | c.1345C>T p.R449* (on ENST00000610905; = p.R344* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 44/224 reads (20%) | catalogued as COSV58765049; called by muse, mutect2, varscan2
- SMCHD1 | c.4903_4904del p.Q1635Vfs*6 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- CDCP1 | c.384T>C p.D128= | Silent (SNP) | VAF 191/451 reads (42%) | catalogued as rs981004849, COSV56106228; called by muse, mutect2, varscan2
- FLG | c.5211C>T p.H1737= | Silent (SNP) | VAF 182/400 reads (46%) | catalogued as rs774101873, COSV64252141; called by muse, mutect2, varscan2
- FUT1 | c.789C>T p.N263= | Silent (SNP) | VAF 57/226 reads (25%) | catalogued as COSV59567793; called by muse, mutect2, varscan2
- HUWE1 | c.11205C>T p.D3735= | Silent (SNP) | VAF 59/107 reads (55%) | catalogued as COSV53351153; called by muse, mutect2, varscan2
- KRTAP6-2 | c.6C>T p.C2= | Silent (SNP) | VAF 57/151 reads (38%) | catalogued as rs201729927, COSV58182857; called by muse, mutect2, varscan2
- KSR2 | c.828G>A p.T276= | Silent (SNP) | VAF 177/437 reads (41%) | catalogued as COSV60382258; called by muse, mutect2, varscan2
- NPAP1 | c.3468G>A p.P1156= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as rs751361960, COSV61506979, COSV61512314; called by muse, mutect2, varscan2
- OR2T4 | c.234C>A p.I78= | Silent (SNP) | VAF 198/650 reads (30%) | catalogued as COSV63543293, COSV63544164, COSV63544348; called by muse, mutect2, varscan2
- PLXNA3 | c.2841G>A p.A947= | Silent (SNP) | VAF 204/358 reads (57%) | catalogued as rs371349360, COSV63754489; called by muse, varscan2
- TAP2 | c.1650G>A p.G550= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV66499859; called by muse, mutect2, varscan2
- VWA7 | c.711G>T p.P237= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV63304401, COSV63304796; called by muse, mutect2
- ZNF528 | c.663C>G p.V221= | Silent (SNP) | VAF 11/267 reads (4%) | catalogued as COSV64618891, COSV64619884; called by muse, mutect2
- FAM183BP | n.1122G>A | RNA (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- KLK8 | c.71-89G>A | Intron (SNP) | VAF 40/180 reads (22%) | catalogued as COSV51593412, COSV99144037; called by muse, mutect2, varscan2
